Somatic mutation profile of tumor specimen C3N-01903-04 (aliquot CPT0381170009) from CPTAC case C3N-01903, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary renal cell carcinoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 48.2 years (17,616 days).
Specimen C3N-01903-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 887ec33c-11d6-400c-8c8c-5e8b57c32a69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01903-31 (Blood Derived Normal), aliquot CPT0381410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdef5b54-3c59-41ff-bc19-13f3129d0746

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, RNA 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRK1 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs775596167; called by muse, mutect2, varscan2
- MME | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1293196436; called by muse, mutect2, varscan2
- CCDC57 | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- EIF3H | c.272A>T p.D91V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- EPPIN | c.144T>A p.C48* | Nonsense Mutation (SNP) | VAF 21/133 reads (16%) | called by muse, mutect2, varscan2
- IMPA2 | c.845A>C p.Y282S | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- LRATD1 | c.159T>G p.F53L | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2
- RUNX1T1 | c.448A>G p.T150A (on ENST00000265814 / NM_001198628.1; = p.T123A on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TAF5 | c.760A>C p.N254H | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN14 | c.1314G>T p.S438= | Silent (SNP) | VAF 64/227 reads (28%) | called by muse, mutect2, varscan2
- SLC17A1 | c.411T>G p.V137= | Silent (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- TBC1D10C | c.675G>A p.V225= | Silent (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- FUNDC2P2 | n.502C>A | RNA (SNP) | VAF 38/424 reads (9%) | called by muse, mutect2
- PDE10A | c.106+91851A>G | Intron (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
